TCGA case TCGA-AR-A2LO — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Mayo. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ad0fa961-c085-4f38-b3db-5fc0cbf6b64f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 46 years; Vital status: Alive.

Diagnoses (1)
1. Lobular carcinoma, NOS: ICD-O-3 morphology code: 8520/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 46.8 years (17,080 days); Year of diagnosis: 2010; Method of diagnosis: Core Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Left Lower Outer.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 16.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Bevacizumab; Days to treatment start: 44 days; Days to treatment end: 161 days; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin Hydrochloride; Days to treatment start: 44 days; Days to treatment end: 84 days; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Days to treatment start: 98 days; Days to treatment end: 175 days; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 196 days; Days to treatment end: 228 days; Treatment dose: 5,000 cGy; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Days to treatment start: 199 days; Days to treatment end: 903 days (2.5 years); Clinical trial indicator: Yes.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Anastrozole; Days to treatment start: 903 days (2.5 years); Treatment outcome: Treatment Ongoing; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.

Follow-up (2 entries)
- Days to follow up: 1,198 days (3.3 years); Disease response: Tumor Free.
- Follow-up contacts recording only the day: day 633, day 935.

Molecular and laboratory tests
- ERBB2 (IHC): Equivocal; Staining intensity value: 2+.
- ERBB2 amplification (FISH): Negative.
- ESR1 (IHC): Positive; Test value range: 70-79%.
- PGR (IHC): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AR-A2LO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 1,650 mg.
  Slide TCGA-AR-A2LO-01A-03-TSC: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-AR-A2LO-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AR-A2LO-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Lymph nodes examined: Yes; Axillary staging method: Sentinel lymph node biopsy plus axillary dissection; Surgical procedure first: Simple Mastectomy; Histologic diagnosis: Infiltrating Lobular Carcinoma; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Her2 IHC score: 2+; Method initial path diagnosis: Core needle biopsy; Prospective collection: No; Retrospective collection: Yes; Metastatic tumor indicator: No.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left Lower Outer Quadrant.
- Follow-up form 1: Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Follow-up form 2: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Adriamycin.
- Drug treatment 2: Pharmaceutical therapy drug name: Cytoxan.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,198 days; disease-specific survival: no event (censored), 1,198 days; disease-free interval: no event (censored), 1,198 days; progression-free interval: no event (censored), 1,198 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AR-A2LO-01A-31D-A19G-01): tumor purity 0.33, ploidy 1.98, whole-genome doublings 0.
